Somatic mutation profile of tumor specimen TCGA-CF-A8HX-01A (aliquot TCGA-CF-A8HX-01A-11D-A364-08) from TCGA case TCGA-CF-A8HX, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 55.5 years (20,259 days).
Specimen TCGA-CF-A8HX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8715a981-7ccc-4858-ae2d-9068f1f174b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CF-A8HX-10A (Blood Derived Normal), aliquot TCGA-CF-A8HX-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e12bf323-a49c-40cc-8e28-d4dd6be1e2ed

The open-access MAF lists 65 somatic variants for this specimen: 45 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 18, Frame Shift Del 1, 5'UTR 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASPA | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs774323189, CM990198, COSV53980884; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RHOA | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 57/132 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as COSV69041798; called by muse, mutect2, varscan2
- ADAMTS15 | c.56C>G p.S19C | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.237); catalogued as COSV54504696; called by muse, mutect2, varscan2
- ASXL1 | c.4029C>G p.N1343K | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.543); catalogued as COSV60106378; called by muse, mutect2, varscan2
- BIRC6 | c.7072C>T p.L2358F | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV70198072; called by muse, mutect2, varscan2
- BMX | c.1019+1G>C p.X340_splice | Splice Site (SNP) | VAF 39/97 reads (40%) | catalogued as COSV59591075; called by muse, mutect2
- BMX | c.1991C>T p.S664F | Missense Mutation (SNP) | VAF 84/198 reads (42%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.931); catalogued as COSV53024599; called by muse, mutect2, varscan2
- CACNA1B | c.5288G>A p.G1763E | Missense Mutation (SNP) | VAF 25/26 reads (96%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1327897420, COSV53122212; called by muse, mutect2, varscan2
- CDC25B | c.313G>A p.E105K (on ENST00000245960 / NM_021873.3; = p.E91K on NM_004358.4) | Missense Mutation (SNP) | VAF 46/82 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs199501910, COSV55655736; called by muse, mutect2, varscan2
- CDH5 | c.2116G>C p.A706P | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.987); catalogued as rs1218766811, COSV100439100; called by muse, mutect2, varscan2
- CHAF1B | c.1544C>A p.P515Q | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as COSV58439783; called by muse, mutect2, varscan2
- CPS1 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs187860166, COSV51807652; called by muse, mutect2, varscan2
- CPT1C | c.678G>C p.W226C | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54918676; called by muse, mutect2, varscan2
- DCLRE1A | c.751C>T p.H251Y | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV63748528; called by muse, mutect2, varscan2
- DIP2C | c.3935G>A p.G1312E | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as COSV55154095; called by muse, mutect2, varscan2
- DNAAF4 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.609); catalogued as COSV58248132; called by muse, mutect2, varscan2
- HCFC1 | c.5492C>A p.P1831Q | Missense Mutation (SNP) | VAF 92/204 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV60071433; called by muse, mutect2, varscan2
- HRNR | c.780C>A p.H260Q | Missense Mutation (SNP) | VAF 162/540 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as COSV64256801; called by muse, mutect2
- HSD17B13 | c.590G>C p.R197T | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as rs762314183, COSV56345737, COSV56345882; called by muse, mutect2, varscan2
- HUWE1 | c.3182G>T p.R1061L | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV53338014, COSV53342246; called by muse, mutect2, varscan2
- ITSN2 | c.2328G>A p.M776I | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1343776132, COSV61945775; called by muse, mutect2, varscan2
- JKAMP | c.956C>T p.S319L (on ENST00000554271 / NM_001284201.1; = p.S305L on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV54199107; called by muse, mutect2, varscan2
- MATR3 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV63076897; called by muse, mutect2, varscan2
- MRPL41 | c.300C>G p.I100M | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); catalogued as rs1258627546, COSV52997515; called by muse, mutect2, varscan2
- MTNR1A | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs747255185, COSV56155162; called by muse, mutect2, varscan2
- MYH6 | c.435G>C p.K145N | Missense Mutation (SNP) | VAF 53/105 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV62449489; called by muse, mutect2, varscan2
- NDEL1 | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55326432; called by muse, mutect2, varscan2
- OPN1MW | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.179); catalogued as rs782812659; called by muse, mutect2, varscan2
- OTOL1 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100019837; called by muse, mutect2
- PPL | c.3379G>A p.E1127K | Missense Mutation (SNP) | VAF 19/21 reads (90%) | SIFT tolerated (0.1); PolyPhen benign (0.397); catalogued as rs769930858, COSV52167388; called by muse, mutect2, varscan2
- PSMA7 | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.072); catalogued as COSV53379854; called by muse, mutect2, varscan2
- RFX7 | c.2392G>C p.E798Q (on ENST00000559447 / NM_001368074.1; = p.E895Q on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57962251; called by muse, mutect2, varscan2
- RP1L1 | c.4870C>A p.L1624M | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.626); catalogued as rs564793913, COSV66754106; called by muse, mutect2, varscan2
- SIL1 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs1016026305, COSV54530790; called by muse, mutect2, varscan2
- SP140 | c.2412C>G p.I804M | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100613545; called by mutect2, varscan2
- STON1 | c.1846C>G p.Q616E | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as COSV59129126; called by muse, mutect2
- TICRR | c.2322G>C p.L774F | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV51537993, COSV51540541; called by muse, mutect2, varscan2
- TIGD5 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as rs1420058415, COSV100363980, COSV57818735; called by muse, mutect2, varscan2
- TMEM39A | c.595C>G p.L199V | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs746080840, COSV59900112; called by muse, mutect2, varscan2
- TNS2 | c.538G>A p.E180K (on ENST00000314250 / NM_170754.4; = p.E190K on NM_015319.2) | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58576602; called by muse, mutect2, varscan2
- TTN | c.42694C>G p.Q14232E (on ENST00000591111; = p.Q6808E on NM_003319.4) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | PolyPhen benign (0.078); catalogued as COSV59993174; called by muse, mutect2, varscan2
- TUFT1 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs898941767, COSV61948456; called by muse, mutect2, varscan2
- UBR4 | c.204G>T p.K68N | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.95); catalogued as COSV64387095; called by muse, mutect2, varscan2
- WNK4 | c.3496C>T p.R1166W | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs770685193, COSV55903374; called by muse, mutect2, varscan2
- PDSS2 | c.680_681del p.Y227Sfs*2 | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | called by pindel, varscan2
- ATP2B3 | c.3027C>T p.I1009= | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as COSV54844523; called by muse, mutect2, varscan2
- CASP2 | c.186G>A p.E62= | Silent (SNP) | VAF 57/124 reads (46%) | catalogued as COSV60081816; called by muse, mutect2, varscan2
- CNGA4 | c.423G>A p.L141= | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as COSV66005203; called by muse, mutect2, varscan2
- CSTF2 | c.204G>A p.E68= | Silent (SNP) | VAF 35/40 reads (88%) | catalogued as COSV63376201; called by muse, mutect2, varscan2
- FOXE3 | c.387C>T p.F129= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as COSV58632604; called by muse, mutect2, varscan2
- HLA-E | c.993G>A p.K331= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as COSV64927448; called by muse, mutect2, varscan2
- IQUB | c.1726C>T p.L576= | Silent (SNP) | VAF 48/95 reads (51%) | catalogued as COSV61238643; called by muse, mutect2, varscan2
- PTGER4 | c.201G>A p.L67= | Silent (SNP) | VAF 27/57 reads (47%) | catalogued as rs924987100, COSV100201509, COSV56720668; called by muse, mutect2, varscan2
- SH3PXD2B | c.924C>T p.N308= | Silent (SNP) | VAF 13/18 reads (72%) | catalogued as rs1199607816, COSV61126196; called by muse, mutect2, varscan2
- SPTB | c.6315C>T p.S2105= | Silent (SNP) | VAF 53/107 reads (50%) | catalogued as rs1164831682, COSV61552041; called by muse, mutect2, varscan2
- SRGAP3 | c.609C>T p.L203= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as rs916860965, COSV64532347; called by muse, mutect2, varscan2
- TAGAP | c.765G>A p.Q255= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV57851217; called by muse, mutect2, varscan2
- TAL1 | c.873C>T p.C291= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs758587375, COSV53746132; called by muse, mutect2, varscan2
- TBX22 | c.684G>A p.E228= | Silent (SNP) | VAF 21/29 reads (72%) | catalogued as rs1157489784, COSV64785635; called by muse, mutect2, varscan2
- TROAP | c.312G>A p.V104= | Silent (SNP) | VAF 56/83 reads (67%) | catalogued as COSV57743669; called by muse, mutect2, varscan2
- TTC24 | c.1431G>A p.V477= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV63997468; called by muse, mutect2, varscan2
- UBE2N | c.213C>T p.F71= | Silent (SNP) | VAF 84/133 reads (63%) | catalogued as COSV58867479; called by muse, mutect2, varscan2
- ZMYM1 | c.1620A>G p.L540= | Silent (SNP) | VAF 85/158 reads (54%) | catalogued as COSV63251513; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 10/20 reads (50%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
- TTBK2 | c.823-7068G>C | Intron (SNP) | VAF 49/108 reads (45%) | called by muse, mutect2, varscan2
